TCGA case TCGA-04-1542 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0c1a2e7d-e7e4-481e-a012-ef214c444497

Demographics
Sex at birth: female; Race: white; Age at index: 52 years; Vital status: Dead; Days to death: 2,561 days (7.0 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 52.7 years (19,263 days); Year of diagnosis: 2001; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIB; Tumor grade: G2; Prior treatment: No.
   Pathology details: Lymphatic invasion present: No; Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 2 days; Days to treatment end: 167 days; Number of cycles: 8; Treatment dose: 5 AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Treatment intent type: Adjuvant; Days to treatment start: 2 days; Days to treatment end: 167 days; Number of cycles: 8; Treatment dose: 17,378 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 2 days; Days to treatment end: 167 days; Number of cycles: 8; Treatment dose: 2,534 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 1,051 days (2.9 years); Days to treatment end: 1,294 days (3.5 years); Number of cycles: 12; Treatment dose: 5 AUC.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 1,051 days (2.9 years); Days to treatment end: 1,294 days (3.5 years); Number of cycles: 12; Treatment dose: 4,004 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 1,322 days (3.6 years); Days to treatment end: 1,487 days (4.1 years); Number of cycles: 6; Treatment dose: 122 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 1,501 days (4.1 years); Days to treatment end: 1,529 days (4.2 years); Number of cycles: 2; Treatment dose: 159 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Recurrent Disease; Days to treatment start: 1,564 days (4.3 years); Days to treatment end: 1,781 days (4.9 years); Number of cycles: 11; Treatment dose: 11,300 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Recurrent Disease; Days to treatment start: 1,564 days (4.3 years); Days to treatment end: 1,781 days (4.9 years); Number of cycles: 11; Treatment dose: 32,496 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Initial disease status: Recurrent Disease; Days to treatment start: 1,993 days (5.5 years); Days to treatment end: 2,106 days (5.8 years); Number of cycles: 6; Treatment dose: 7,398 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Initial disease status: Recurrent Disease; Days to treatment start: 2,115 days (5.8 years); Days to treatment end: 2,176 days (6.0 years); Number of cycles: 4; Treatment dose: 4,875 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Recurrent Disease; Days to treatment start: 2,115 days (5.8 years); Days to treatment end: 2,176 days (6.0 years); Number of cycles: 4; Treatment dose: 124 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 2,207 days (6.0 years); Days to treatment end: 2,268 days (6.2 years); Number of cycles: 3; Treatment dose: 5 AUC.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin; Initial disease status: Recurrent Disease; Days to treatment start: 2,268 days (6.2 years); Days to treatment end: 2,328 days (6.4 years); Number of cycles: 3; Treatment dose: 343 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Initial disease status: Recurrent Disease; Days to treatment start: 2,328 days (6.4 years); Days to treatment end: 2,512 days (6.9 years); Number of cycles: 9; Treatment dose: 2,870 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Recurrent Disease; Days to treatment start: 2,328 days (6.4 years); Days to treatment end: 2,512 days (6.9 years); Number of cycles: 9; Treatment dose: 28,756 mg.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 55.5 years (20,283 days); Days to diagnosis: 1,020 days (2.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 1,020 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 1,020 days (2.8 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 2,561 days (7.0 years); Disease response: With Tumor.
- ECOG performance status: 0; Timepoint: Preoperative.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-04-1542-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.3.
  Slide TCGA-04-1542-01A-01-TS1: Section location: Top; Percent tumor cells: 79; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 20.
  Slide TCGA-04-1542-01A-01-BS1: Section location: Bottom; Percent tumor cells: 63; Percent tumor nuclei: 80; Percent normal cells: 42; Percent necrosis: 5; Percent stromal cells: 0.
- Sample TCGA-04-1542-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: No.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: Carbplatin.
- Drug treatment 7: Pharmaceutical therapy drug name: Avastin.
- Drug treatment 16: Pharmaceutical therapy drug name: Doxil.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,561 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,561 days; disease-free interval: event (new tumor event after initially disease-free), 1,020 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,020 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-04-1542-01A-01D-0497-01): tumor purity 0.94, ploidy 3.1, whole-genome doublings 1.
